CPTAC case C3L-09552 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6edb1c39-fc26-415e-8551-054c696d0b24

Demographics
Sex at birth: male; Race: white; Year of birth: 1976; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Fundus of stomach; Age at diagnosis: 46.3 years (16,900 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Residual disease: RX; Days to last known disease status: 1,065 days (2.9 years); Progression or recurrence: no; Days to last follow up: 1,065 days (2.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 44.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Days to treatment start: 28 days; Days to treatment end: 50 days; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 463 days (1.3 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 841 days (2.3 years); Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09552-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 235 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09552-24: Section location: Fundus; Percent tumor nuclei: 75; Percent necrosis: 0.
- Sample C3L-09552-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -13 days; Method of sample procurement: Blood Draw.
